Somatic mutation profile of tumor specimen TCGA-19-A60I-01A (aliquot TCGA-19-A60I-01A-12D-A33T-08) from TCGA case TCGA-19-A60I, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 39.5 years (14,437 days).
Specimen TCGA-19-A60I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 29da3a0b-c832-4c72-927c-d3ffb6cf1ba9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-19-A60I-10A (Blood Derived Normal), aliquot TCGA-19-A60I-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e323af2-20b1-4fcb-b5df-313d504a0f57

The open-access MAF lists 31 somatic variants for this specimen: 21 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 8, RNA 1, Splice Region 1, Intron 1, Nonsense Mutation 1, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNG5 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs1333562967, COSV50055154; called by muse, mutect2, varscan2
- CADPS | c.2300G>A p.G767E | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99337315; called by muse, mutect2, varscan2
- CCDC141 | c.2752A>G p.K918E | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99836584; called by muse, mutect2, varscan2
- CCDC172 | c.103C>T p.R35C | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs868026474, COSV100319718, COSV100319989, COSV60937199; called by muse, mutect2, varscan2
- CRNN | c.62C>T p.T21M | Missense Mutation (SNP) | VAF 54/105 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.085); catalogued as rs201339909; called by muse, mutect2
- EPRS1 | c.1347A>G p.G449= | Splice Region (SNP) | VAF 19/36 reads (53%) | catalogued as COSV100859355; called by muse, mutect2, varscan2
- GGT1 | c.1401G>A p.M467I | Missense Mutation (SNP) | VAF 39/48 reads (81%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as rs1281315722, COSV99958765; called by muse, mutect2, varscan2
- GRK7 | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs751671473, COSV53822623; called by muse, mutect2, varscan2
- KLC4 | c.1759C>T p.R587* | Nonsense Mutation (SNP) | VAF 16/50 reads (32%) | catalogued as COSV99431709; called by muse, mutect2, varscan2
- KRT27 | c.756C>A p.D252E | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.818); catalogued as rs779267418, COSV100053235; called by muse, mutect2, varscan2
- LANCL1 | c.982A>G p.N328D | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99286254; called by muse, mutect2, varscan2
- NCAPG2 | c.1600G>A p.E534K | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV99316815; called by muse, mutect2, varscan2
- SCGB1D1 | c.244-1G>A p.X82_splice | Splice Site (SNP) | VAF 11/36 reads (31%) | catalogued as COSV100086676; called by muse, mutect2, varscan2
- SERTAD4 | c.1009C>T p.R337W | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs150924683; called by muse, mutect2, varscan2
- SGCE | c.977G>A p.R326H (on ENST00000647096; = p.R290H on NM_003919.3) | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.006); catalogued as rs748001731, COSV99722132; called by muse, mutect2, varscan2
- SLC1A6 | c.1178C>T p.T393M | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1242273336, COSV99693603; called by muse, mutect2, varscan2
- SPEF2 | c.3625C>A p.P1209T | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100607006, COSV61554636; called by muse, mutect2, varscan2
- TAF1L | c.976G>A p.A326T | Missense Mutation (SNP) | VAF 50/111 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs756820373, COSV54257507, COSV99644464; called by muse, mutect2, varscan2
- ZNF341 | c.2201G>A p.G734D (on ENST00000375200 / NM_001282935.1; = p.G727D on NM_032819.4) | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.053); catalogued as rs1424225690, COSV100677819; called by muse, mutect2, varscan2
- FCGBP | c.2660C>T p.T887M | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- RB1 | c.2091_2093del p.D697_R698delinsE | In Frame Del (DEL) | VAF 12/18 reads (67%) | called by mutect2, varscan2
- ARHGEF7 | c.2238T>C p.A746= (on ENST00000375741 / NM_001113511.2; = p.A725= on NM_145735.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 24/38 reads (63%) | catalogued as COSV99521366; called by muse, mutect2, varscan2
- GALNT14 | c.1146C>T p.F382= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as rs1480740304, COSV61103842; called by muse, mutect2, varscan2
- HEPH | c.2721C>T p.I907= (on ENST00000343002; = p.I640= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/30 reads (87%) | catalogued as COSV100294612, COSV57973389; called by muse, mutect2, varscan2
- LAMA3 | c.9648G>A p.T3216= (on ENST00000313654 / NM_198129.4; = p.T1607= on NM_000227.6) | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as rs758630001, COSV99334483; called by muse, mutect2
- LRP2 | c.3735G>A p.P1245= | Silent (SNP) | VAF 54/95 reads (57%) | catalogued as COSV55569092, COSV55576915; called by muse, mutect2, varscan2
- MAG | c.1455C>T p.R485= | Silent (SNP) | VAF 22/78 reads (28%) | catalogued as COSV62701448; called by muse, mutect2, varscan2
- QSER1 | c.3999C>T p.D1333= (on ENST00000399302; = p.D1462= on NM_001076786.3) | Silent (SNP) | VAF 36/81 reads (44%) | catalogued as COSV101234810; called by muse, mutect2, varscan2
- TRPM1 | c.720C>T p.N240= | Silent (SNP) | VAF 38/101 reads (38%) | catalogued as COSV99855733; called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85626G>A | Intron (SNP) | VAF 39/91 reads (43%) | catalogued as rs758712018, COSV72280978; called by muse, mutect2, varscan2
- NBPF25P | n.1709C>A | RNA (SNP) | VAF 29/102 reads (28%) | catalogued as rs1420908563; called by muse, mutect2, varscan2
